Somatic mutation profile of tumor specimen C3N-00733-02 (aliquot CPT0025890012) from CPTAC case C3N-00733, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.1 years (20,507 days).
Specimen C3N-00733-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64c9058e-722d-4243-8b29-1c98fee3fc5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00733-31 (Blood Derived Normal), aliquot CPT0028480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e72ac7f-c8f6-40cd-991d-365d51240c4a

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 7, Frame Shift Del 4, Intron 3, Nonsense Mutation 3, Splice Site 2, RNA 2, In Frame Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+1G>T p.X114_splice | Splice Site (SNP) | VAF 71/313 reads (23%) | hotspot (GDC flag); catalogued as rs730882032, CS044968, CS982396, COSV56543763, COSV56544858, COSV56545042, COSV56546938; called by muse, mutect2, varscan2
- ADAMTS12 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs777630888, COSV100711434, COSV61275688; called by muse, mutect2, varscan2
- CDA | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV66751646; called by muse, mutect2, varscan2
- CRACD | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs761571893, COSV51721568, COSV51729215; called by muse, mutect2, varscan2
- HMCN1 | c.8596C>A p.L2866I | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99629176; called by muse, mutect2
- IRX4 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99180752; called by muse, mutect2, varscan2
- KRTAP10-5 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 43/714 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1215319562; called by muse, mutect2
- LRFN4 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs773088818; called by muse, mutect2, varscan2
- PKD1 | c.9569G>A p.G3190E | Missense Mutation (SNP) | VAF 124/749 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM158591; called by muse, mutect2, varscan2
- TRAM1L1 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60292663; called by muse, mutect2
- TRPV2 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as rs369223814; called by mutect2, varscan2
- ABCC2 | c.3615-6_3631del p.X1205_splice | Splice Site (DEL) | VAF 42/476 reads (9%) | called by mutect2, pindel
- BRI3BP | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- C19orf25 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCNO | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CEMIP2 | c.994del p.E332Nfs*7 | Frame Shift Del (DEL) | VAF 6/101 reads (6%) | called by mutect2, pindel*
- CHP2 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CLPB | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CNOT10 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CPD | c.1595C>A p.S532* | Nonsense Mutation (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- DMD | c.4269T>A p.S1423R | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- DNAH11 | c.13071_13075dup p.R4359Hfs*30 | Frame Shift Ins (INS) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- DOCK1 | c.3244C>A p.P1082T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DPP4 | c.2030A>T p.E677V | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DSPP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 128/832 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, varscan2
- DUSP9 | c.314del p.V105Gfs*79 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- HECTD4 | c.11213_11230del p.R3738_P3743del | In Frame Del (DEL) | VAF 34/174 reads (20%) | called by mutect2, pindel
- HMCN1 | c.13735_13742del p.Q4579Afs*7 | Frame Shift Del (DEL) | VAF 74/574 reads (13%) | called by mutect2, pindel
- IGSF10 | c.4854G>C p.K1618N | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2
- IL1RAPL2 | c.585_596del p.K195_L199delinsN | In Frame Del (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- KMT2C | c.14279C>G p.S4760W | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNL1 | c.5303_5316del p.Y1768Ffs*4 (on ENST00000346991 / NM_170589.5; = p.Y1742Ffs*4 on NM_144508.5) | Frame Shift Del (DEL) | VAF 13/135 reads (10%) | called by mutect2, pindel
- LRP2 | c.2551A>G p.I851V | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- LRRFIP1 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.038); called by muse, mutect2
- MAP3K1 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAPK7 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC2 | c.1835A>G p.K612R | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2
- NCAM2 | c.1551C>G p.N517K | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFAF4 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PBRM1 | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- PCDHA11 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 107/713 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTN4RL2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SLC35A2 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK3 | c.657C>A p.H219Q | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SORCS2 | c.2566A>T p.N856Y | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPDYC | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- STIP1 | c.1492A>C p.I498L | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUFU | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRIM60 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC3 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNK3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF611 | c.1398T>G p.S466R | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5C | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, varscan2
- AXIN2 | c.987T>C p.S329= | Silent (SNP) | VAF 40/452 reads (9%) | called by muse, mutect2
- CLUH | c.3177C>T p.P1059= (on ENST00000435359; = p.P1098= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- FERMT3 | c.294G>T p.R98= | Silent (SNP) | VAF 58/370 reads (16%) | called by muse, mutect2, varscan2
- PTCH1 | c.1257G>A p.V419= | Silent (SNP) | VAF 97/391 reads (25%) | catalogued as rs1060504535; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RGPD4 | c.4086A>T p.A1362= | Silent (SNP) | VAF 143/735 reads (19%) | called by muse, mutect2, varscan2
- RMC1 | c.1216C>T p.L406= | Silent (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- ZNF292 | c.6504T>G p.T2168= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- BCL2L10 | c.489+34G>T | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, varscan2
- CSF2RA | c.*145C>T | 3'UTR (SNP) | VAF 37/170 reads (22%) | catalogued as rs750257726, COSV100817396; called by muse, mutect2, varscan2
- GVINP1 | n.5046dup | RNA (INS) | VAF 19/194 reads (10%) | called by mutect2, pindel, varscan2
- HNF4A-AS1 | n.356+1330C>A | Intron (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- KRT17P1 | n.1073G>T | RNA (SNP) | VAF 58/1148 reads (5%) | called by muse, mutect2
- MEIS1 | c.1114+36G>A | Intron (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2
